Gene-level copy-number profile of tumor specimen TARGET-51-PAJPFB-01A from TARGET case TARGET-51-PAJPFB, project TARGET-CCSK (Clear Cell Sarcoma of the Kidney). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell sarcoma of kidney; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 1.4 years (505 days).
Specimen TARGET-51-PAJPFB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-CCSK.bd8fea7d-6a51-5165-893e-4b5669603c0a.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-51-PAJPFB-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 388 have no estimate.
https://portal.gdc.cancer.gov/files/00cfd97c-b6c5-44eb-86ed-45d572d06757

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2,396; copy number 1: 105; copy number 2: 57,177; copy number 3: 296; copy number 4: 260; copy number 5: 1.

Homozygous deletions (total copy number 0; autosomes only): 9 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:10,006,482–10,009,725, 1 gene: SLC2A9-AS1.
- chr6:31,394,289–31,478,936, 7 genes: AL645933.2, MICA, AL645933.3, Y_RNA, LINC01149, AL645933.1, HCP5.
- chr14:104,400,943–104,401,048, 1 gene: RNU6-684P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:157,232,231–157,237,136, 1 gene, copy number 5: AL138900.1.

Autosomal genes at a single copy (total copy number 1): 103. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
